Somatic mutation profile of tumor specimen TCGA-DO-A2HM-01B (aliquot TCGA-DO-A2HM-01B-11D-A22D-08) from TCGA case TCGA-DO-A2HM, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 49.5 years (18,068 days).
Specimen TCGA-DO-A2HM-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1edc4a63-2ddb-49ab-b3dc-cbaba59214f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DO-A2HM-10B (Blood Derived Normal), aliquot TCGA-DO-A2HM-10B-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa7310d2-073d-4907-9dba-faad1d84e33a

The open-access MAF lists 67 somatic variants for this specimen: 48 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 17, Nonsense Mutation 4, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA1 | c.1049C>G p.S350W | Missense Mutation (SNP) | VAF 15/282 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as CM034515, COSV64202849, COSV64203694; called by muse, mutect2
- ALOX12B | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as rs781269323, COSV59872371; called by muse, mutect2
- ANGPTL1 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52367153; called by muse, mutect2
- ARID2 | c.3091C>T p.Q1031* | Nonsense Mutation (SNP) | VAF 11/98 reads (11%) | catalogued as rs868082376, COSV57609049; called by muse, mutect2
- ARRDC2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV55845293; called by muse, mutect2
- BCL2L14 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV53787591; called by muse, mutect2
- BNIP1 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV51571184; called by muse, mutect2, varscan2
- CCNJ | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 16/212 reads (8%) | catalogued as COSV56443655; called by muse, mutect2
- CD38 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56891573; called by muse, mutect2, varscan2
- CEMIP2 | c.4048G>C p.E1350Q | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.376); catalogued as COSV65488209; called by muse, mutect2
- CFAP46 | c.6867-1G>C p.X2289_splice | Splice Site (SNP) | VAF 11/80 reads (14%) | catalogued as COSV54155061; called by muse, mutect2, varscan2
- CHD3 | c.1530G>C p.Q510H | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57877483, COSV57880717; called by muse, mutect2
- CNIH2 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100268309, COSV61012748; called by muse, mutect2
- CTCF | c.1741G>C p.D581H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV50482222; called by muse, mutect2, varscan2
- EBPL | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54432832; called by muse, mutect2
- EIF3D | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV53403538, COSV53404251; called by muse, mutect2, varscan2
- ERCC3 | c.1671G>C p.K557N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53428312; called by muse, mutect2, varscan2
- FBXO11 | c.2030G>C p.R677T (on ENST00000403359 / NM_001190274.2; = p.R593T on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.479); catalogued as COSV52283118; called by muse, mutect2, varscan2
- FGD2 | c.1627G>C p.D543H | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs762286725, COSV51464708; called by muse, mutect2
- FLII | c.2607G>C p.K869N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV57499213; called by muse, mutect2, varscan2
- FZR1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV58052524; called by muse, mutect2, varscan2
- GPR158 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV100894207, COSV66275892; called by muse, mutect2
- GRIN2B | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.8); catalogued as COSV74206741; called by muse, mutect2
- HDGFL2 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); catalogued as rs755573744, COSV56683852; called by muse, mutect2, varscan2
- HID1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs752788202, COSV59351194; called by muse, mutect2
- ITPR1 | c.2404G>A p.V802M (on ENST00000354582; = p.V787M on NM_002222.7) | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs369080877; called by muse, mutect2
- KCNIP2 | c.769G>A p.E257K (on ENST00000356640 / NM_173191.3; = p.E272K on NM_014591.5) | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as COSV53307838, COSV99493625; called by muse, mutect2
- KLF6 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.151); catalogued as COSV51494677; called by muse, mutect2
- MACF1 | c.21151G>A p.D7051N (on ENST00000372915; = p.D5096N on NM_012090.5) | Missense Mutation (SNP) | VAF 13/196 reads (7%) | catalogued as COSV57122779, COSV57131259; called by muse, mutect2
- MUC7 | c.353C>G p.S118* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as COSV59216987, COSV59219305; called by muse, mutect2
- NNT | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52927019; called by muse, mutect2
- NPRL2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.124); catalogued as rs1452759164, COSV51602949; called by muse, mutect2
- PACSIN3 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV54066712; called by muse, mutect2
- PARP14 | c.4593C>G p.I1531M | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as COSV71735108; called by muse, mutect2
- PPP1R13L | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62909052; called by muse, mutect2, varscan2
- PPP2R5D | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV55151128; called by muse, mutect2
- PRDM8 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV60204160; called by muse, mutect2, varscan2
- PSG5 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as COSV61654687; called by muse, mutect2
- PTPN22 | c.1624C>T p.P542S (on ENST00000359785 / NM_001193431.2; = p.P487S on NM_012411.5) | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.559); catalogued as COSV63085759; called by muse, mutect2
- RELCH | c.3001G>A p.D1001N | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.103); catalogued as COSV56888429; called by muse, mutect2
- SLC12A4 | c.2887G>C p.E963Q | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.251); catalogued as COSV50453445; called by muse, mutect2
- SLC12A5 | c.1000G>C p.E334Q (on ENST00000454036 / NM_001134771.2; = p.E311Q on NM_020708.5) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.041); catalogued as COSV54789475, COSV54797004; called by muse, mutect2
- SMPD4 | c.2344G>A p.E782K (on ENST00000409031 / NM_017951.4; = p.E753K on NM_017751.4) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.164); catalogued as COSV100302390; called by muse, mutect2
- SYT17 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs767243867, COSV62547080; called by muse, mutect2, varscan2
- TENM4 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 30/293 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1201218759, COSV53645877; called by muse, mutect2, varscan2
- TIAM2 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV59697810; called by muse, mutect2, varscan2
- TMC5 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV66867332; called by muse, mutect2
- UBR1 | c.1229G>C p.R410T | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV51932852; called by muse, mutect2
- ALAS1 | c.717C>T p.L239= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV59628619; called by muse, mutect2
- COPZ1 | c.399G>A p.V133= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV50432787; called by muse, mutect2, varscan2
- CPEB4 | c.1161G>A p.E387= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as COSV54173961; called by muse, mutect2
- FLT4 | c.1833G>A p.K611= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as rs1267970737, COSV56114735; called by muse, mutect2
- GIPC3 | c.471C>T p.I157= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as rs1261394877, COSV59259926; called by muse, mutect2
- GRIN2B | c.747G>A p.L249= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as COSV74204859; called by muse, mutect2
- INSRR | c.825C>T p.V275= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1332777438, COSV63875171; called by muse, mutect2, varscan2
- IRS1 | c.663C>T p.F221= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as rs745659344, COSV59337956; called by muse, mutect2
- ITGA2B | c.1401C>T p.I467= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs766997708, COSV52231081, COSV52234954; called by muse, mutect2, varscan2
- JADE3 | c.951G>A p.L317= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs782276374, COSV54465759, COSV54468286; called by muse, mutect2, varscan2
- MYH3 | c.5493G>A p.Q1831= | Silent (SNP) | VAF 24/301 reads (8%) | catalogued as COSV56867148; called by muse, mutect2
- NLRP14 | c.1371C>G p.V457= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV55069434, COSV55072580; called by muse, mutect2
- PRKD2 | c.2610G>A p.G870= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1053932444, COSV52188061; called by muse, mutect2, varscan2
- RAG1 | c.2922C>T p.F974= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV55026357; called by muse, mutect2
- SGSM3 | c.1152C>G p.L384= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99960312; called by muse, mutect2, varscan2
- TNF | c.99C>T p.L33= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV69305049; called by muse, mutect2
- TPT1 | c.210C>T p.V70= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV58539008; called by muse, mutect2
- LAMP2 | c.1093+2565C>G | Intron (SNP) | VAF 8/46 reads (17%) | catalogued as rs876657846, COSV52353928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNORD115-3 | n.76G>A | RNA (SNP) | VAF 18/269 reads (7%) | called by muse, mutect2
